Somatic mutation profile of tumor specimen 0DVHB1 from CCDI case PBCJYX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,579 days).
Specimen 0DVHB1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 381d24a8-e926-4880-a5ed-8b72922c4baa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVHAX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/155f6829-36e4-4e0f-93be-59e5be69d2d8

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 3'UTR 2, Intron 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MORC1 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 52/748 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777865307, COSV51719668; called by muse, mutect2
- OR2W3 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV64456203; called by muse, mutect2
- ZBED5 | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.063); catalogued as rs780011941; called by muse, varscan2
- ABCC3 | c.2720T>G p.L907R | Missense Mutation (SNP) | VAF 127/554 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- ZNF516 | c.2935A>T p.S979C | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- HTR4 | c.279T>C p.C93= | Silent (SNP) | VAF 197/742 reads (27%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 29/297 reads (10%) | called by muse, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 18/180 reads (10%) | catalogued as rs1415560984; called by mutect2, varscan2
- MAN2B1 | c.-13A>C | 5'UTR (SNP) | VAF 17/410 reads (4%) | catalogued as rs923651015; called by muse, mutect2
- STAMBPL1 | c.*41T>C | 3'UTR (SNP) | VAF 14/328 reads (4%) | called by muse, mutect2
